Somatic mutation profile of tumor specimen MP2PRT-PAUFBN-TMP1-A (aliquot MP2PRT-PAUFBN-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUFBN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,058 days).
Specimen MP2PRT-PAUFBN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bae06b48-7712-4574-b80c-7dcc504b4d4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFBN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFBN-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fb06e5a-9706-4b85-ab36-ef5bd5d8cadd

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMRT3 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 170/423 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV99505738; called by muse, mutect2, varscan2
- GRM3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 71/437 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV64471156; called by muse, mutect2, varscan2
- H2AC15 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100357157; called by muse, mutect2, varscan2
- HELZ2 | c.2813G>A p.R938Q (on ENST00000467148 / NM_001037335.2; = p.R369Q on NM_033405.3) | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1344458492, COSV64409607; called by muse, mutect2
- MAP3K10 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1231011085; called by muse, mutect2
- NRXN3 | c.2374G>A p.V792M (on ENST00000335750 / NM_001330195.2; = p.V419M on NM_004796.6) | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478473675, COSV59745379; called by muse, mutect2, varscan2
- PADI4 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1000178880; called by muse, mutect2, varscan2
- ESR1 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 203/439 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- H3C7 | c.83A>T p.K28I | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- LONRF3 | c.168A>C p.Q56H | Missense Mutation (SNP) | VAF 57/595 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.275); called by muse, mutect2
- NR3C1 | c.1184+1_1184+2insGT p.X395_splice | Splice Site (INS) | VAF 56/125 reads (45%) | called by mutect2, pindel, varscan2
- PRKCE | c.1786C>A p.L596M | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYHR1 | c.927C>T p.D309= | Silent (SNP) | VAF 47/320 reads (15%) | catalogued as rs751669212, COSV101446226, COSV71324709; called by muse, mutect2, varscan2
- CYLC2 | c.783G>A p.K261= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as COSV66336937; called by muse, mutect2
- RALGAPA1 | c.1887C>A p.I629= | Silent (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
